Gene-level copy-number profile of tumor specimen TCGA-D8-A1JI-01A from TCGA case TCGA-D8-A1JI, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 55.0 years (20,072 days).
Specimen TCGA-D8-A1JI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.06007408-83ae-42dd-b7ea-bd017e97669f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1JI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/19294c15-6c48-44c9-8d2f-aff7cd6ff788

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 9,283; copy number 3: 8,310; copy number 4: 37,381; copy number 5: 2,694; copy number 6: 1,817; copy number 7: 190; copy number 8: 22; copy number 9: 88; copy number 10: 14; copy number 11: 4; copy number 13: 4; copy number 15: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1JI-01A-11D-A13J-01): tumor purity 0.89, ploidy 1.76, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 122 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:122,697,735–122,702,922, 2 genes, copy number 10: RNF133, RNF148.
- chr9:126,270,121–126,704,691, 12 genes, copy number 10: AL162391.2, AL162391.1, MVB12B, NRON, SNORD116, AL356309.2, AL356309.3, AL356309.1, AL161908.1, LMX1B, AL161908.2, AL161731.1.
- chr11:66,070,272–66,267,860, 4 genes, copy number 13 (within-gene range 6–13): PACS1, AP000759.1, KLC2, AP001107.4.
- chr11:67,317,871–68,449,275, 67 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr11:69,641,156–69,675,416, 2 genes, copy number 9: CCND1, LTO1.
- chr11:69,909,184–71,452,868, 34 genes, copy number 9–15: AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1.
- chr11:71,473,503–71,473,568, 1 gene, copy number 11: MIR6754.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
